Somatic mutation profile of tumor specimen C3N-01016-02 (aliquot CPT0083780006) from CPTAC case C3N-01016, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 56.9 years (20,787 days).
Specimen C3N-01016-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3990d466-bc0b-46af-9000-fcbf421bd26d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01016-71 (Blood Derived Normal), aliquot CPT0083830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68498925-806d-4b4c-a6d0-8052a702be37

The open-access MAF lists 476 somatic variants for this specimen: 337 protein-altering or splice-affecting, 83 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 299, Silent 83, Nonsense Mutation 20, Intron 20, 3'UTR 14, Splice Site 8, RNA 8, 5'Flank 7, Splice Region 5, 5'UTR 5, Frame Shift Del 4, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 178/448 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.13528G>T p.A4510S | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs397516510, CM043079, COSV63693754; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.586G>C p.G196R | Missense Mutation (SNP) | VAF 40/78 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58828092; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3485G>A p.R1162H | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV65887428; called by muse, mutect2, varscan2
- ADCY10 | c.2115C>G p.I705M | Missense Mutation (SNP) | VAF 49/213 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV63245047; called by muse, mutect2, varscan2
- ADGRD2 | c.1486C>T p.R496C | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.594); catalogued as rs778718767, COSV58341383; called by muse, mutect2, varscan2
- AKAP1 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as rs746420376; called by muse, mutect2
- ANK2 | c.8672C>A p.P2891H | Missense Mutation (SNP) | VAF 233/568 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.247); catalogued as COSV52167387; called by muse, mutect2, varscan2
- ANKRD52 | c.784G>T p.G262* | Nonsense Mutation (SNP) | VAF 63/469 reads (13%) | catalogued as COSV57285544; called by muse, mutect2, varscan2
- ARFGAP1 | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1274958197; called by muse, mutect2, varscan2
- ARHGAP9 | c.1016G>T p.R339L | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs372030739; called by muse, mutect2, varscan2
- ATP2B3 | c.2996G>T p.G999V | Missense Mutation (SNP) | VAF 151/255 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54851922; called by muse, mutect2, varscan2
- ATP6V1FNB | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 90/409 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs1340413922; called by muse, mutect2, varscan2
- ATP8A1 | c.2120G>C p.G707A | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as rs916193797, COSV100045769; called by muse, mutect2, varscan2
- BAHD1 | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV69084137; called by muse, mutect2, varscan2
- BCKDHB | c.650G>A p.S217N | Missense Mutation (SNP) | VAF 42/281 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV57508789; called by muse, mutect2, varscan2
- BLK | c.1396C>G p.R466G | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs767202084; called by muse, mutect2, varscan2
- CACNA1B | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53137275; called by muse, mutect2, varscan2
- CACNA1C | c.6352G>T p.G2118W (on ENST00000399634 / NM_001167625.1; = p.G2047W on NM_000719.7) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV100220830; called by muse, mutect2, varscan2
- CARD14 | c.932G>T p.R311L | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV100712443; called by muse, mutect2, varscan2
- CDH10 | c.936C>A p.D312E | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.711); catalogued as COSV52574806, COSV52583443; called by muse, mutect2, varscan2
- CDH9 | c.500G>T p.S167I | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as COSV99144635; called by muse, varscan2
- CHRNB1 | c.472T>C p.F158L | Missense Mutation (SNP) | VAF 81/409 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as rs961261483; called by muse, mutect2, varscan2
- CHST6 | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 58/366 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60001265; called by muse, mutect2, varscan2
- CIITA | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 50/777 reads (6%) | catalogued as COSV100162377; called by muse, mutect2
- CLVS2 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV51561093; called by muse, mutect2, varscan2
- COL11A1 | c.2891G>T p.G964V | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100616779; called by muse, mutect2, varscan2
- COL27A1 | c.1969C>A p.P657T | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs369858706; called by muse, mutect2, varscan2
- CSF2RA | c.291C>G p.H97Q | Missense Mutation (SNP) | VAF 158/609 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs76312561, COSV62624245; called by muse, mutect2, varscan2
- CSPP1 | c.1093G>T p.G365W (on ENST00000676605; = p.G324W on NM_024790.6) | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51580201; called by muse, mutect2, varscan2
- DEAF1 | c.1642G>A p.V548I | Missense Mutation (SNP) | VAF 27/419 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.274); catalogued as rs1472386316, COSV51563211; called by muse, mutect2
- DEPDC5 | c.3460G>T p.G1154C (on ENST00000400246; = p.G1223C on NM_014662.5) | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99836875; called by muse, mutect2, varscan2
- DNAH5 | c.13055G>T p.R4352L | Missense Mutation (SNP) | VAF 165/443 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54222229; called by muse, mutect2, varscan2
- DOCK3 | c.3209G>A p.R1070H | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1337092126; called by muse, mutect2, varscan2
- ECHS1 | c.458A>T p.Y153F | Missense Mutation (SNP) | VAF 75/149 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as COSV100881915; called by muse, mutect2, varscan2
- EIF5AL1 | c.428A>T p.E143V | Missense Mutation (SNP) | VAF 142/385 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs1476172724; called by muse, mutect2, varscan2
- EPHA5 | c.2099G>A p.R700K | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.991); catalogued as rs763587410, COSV56684140; called by muse, mutect2, varscan2
- FAM71B | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 43/267 reads (16%) | catalogued as COSV57231169; called by muse, mutect2, varscan2
- FLNC | c.7225C>A p.R2409S | Missense Mutation (SNP) | VAF 68/316 reads (22%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.74); catalogued as COSV57951527; called by muse, mutect2, varscan2
- GABBR2 | c.2777G>C p.R926P | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99412110; called by muse, mutect2
- GALNS | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 14/127 reads (11%) | catalogued as CM1314335; called by muse, mutect2, varscan2
- GET4 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs764382449, COSV56213948; called by muse, mutect2, varscan2
- GIMAP8 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 53/257 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV56229777; called by muse, mutect2, varscan2
- GPX6 | c.542G>A p.W181* | Nonsense Mutation (SNP) | VAF 59/357 reads (17%) | catalogued as COSV62656924; called by muse, mutect2, varscan2
- IGKV3-15 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 66/778 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs574841516; called by muse, mutect2
- ITIH6 | c.1925G>T p.G642V | Missense Mutation (SNP) | VAF 97/166 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV99513264; called by muse, mutect2, varscan2
- JPH1 | c.390G>C p.Q130H | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100646725; called by muse, mutect2, varscan2
- KCNB2 | c.673G>T p.G225* | Nonsense Mutation (SNP) | VAF 102/285 reads (36%) | catalogued as COSV101578615, COSV101578778; called by muse, mutect2, varscan2
- KCNB2 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV73049224; called by muse, mutect2, varscan2
- KCNK9 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 363/797 reads (46%) | catalogued as COSV57280392; called by muse, varscan2
- KCNT1 | c.2699C>A p.T900K (on ENST00000488444; = p.T919K on NM_020822.3) | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53710912; called by muse, mutect2, varscan2
- KIF26A | c.371G>C p.R124P | Missense Mutation (SNP) | VAF 196/591 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV104408684; called by muse, mutect2, varscan2
- KLHL28 | c.592G>T p.V198F | Missense Mutation (SNP) | VAF 154/272 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs911755273; called by mutect2, varscan2
- KLHL32 | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65110725; called by muse, mutect2, varscan2
- LMX1A | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 107/310 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.393); catalogued as rs528275002; called by muse, mutect2, varscan2
- LRFN1 | c.1632C>G p.I544M | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99952764; called by muse, mutect2, varscan2
- MAGED2 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.402); catalogued as COSV99514703; called by muse, mutect2, varscan2
- MAGEL2 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.15); catalogued as rs1175737367; called by muse, mutect2, varscan2
- MAP2 | c.3104A>G p.E1035G | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV99560627; called by muse, mutect2, varscan2
- MEOX1 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.663); catalogued as rs1004663843; called by muse, mutect2, varscan2
- MPDZ | c.1666G>T p.V556L | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.097); catalogued as rs148348858; called by muse, mutect2, varscan2
- MSC | c.331G>C p.A111P | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57696401, COSV57696868; called by muse, mutect2, varscan2
- MYCBP2 | c.4333A>G p.T1445A (on ENST00000357337; = p.T1483A on NM_015057.5) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs535457031; called by muse, mutect2, varscan2
- MYH11 | c.334G>T p.G112W | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55566926; called by muse, mutect2, varscan2
- MYH13 | c.5039G>T p.R1680L | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747286137, COSV52829934; called by muse, mutect2, varscan2
- N6AMT1 | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs1208344616; called by muse, mutect2
- NFATC4 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755808600, COSV51597241; called by muse, mutect2, varscan2
- NLRP5 | c.2191C>T p.P731S | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs747733412; called by muse, mutect2, varscan2
- NPHS2 | c.873+3G>A | Splice Region (SNP) | VAF 92/396 reads (23%) | catalogued as rs777830598; called by muse, mutect2, varscan2
- NSMF | c.122G>T p.R41L | Missense Mutation (SNP) | VAF 125/286 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV52999001; called by muse, mutect2, varscan2
- OMG | c.889C>G p.Q297E | Missense Mutation (SNP) | VAF 96/561 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99049975; called by muse, mutect2, varscan2
- OR10H2 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.084); catalogued as rs1277064124, COSV59945744; called by muse, mutect2, varscan2
- OR11H6 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as rs946398048, COSV59643724; called by muse, mutect2, varscan2
- OR1C1 | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV68715739; called by muse, mutect2, varscan2
- OR1L8 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); catalogued as rs372497222; called by muse, mutect2, varscan2
- OR2A25 | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 66/345 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV101376409; called by muse, mutect2, varscan2
- OR2A25 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 66/343 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.012); catalogued as rs535176961; called by muse, mutect2, varscan2
- OR2M3 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 170/534 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71759375; called by muse, mutect2, varscan2
- OR2T6 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV63216742; called by muse, mutect2, varscan2
- OR4A5 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs376153513; called by muse, mutect2, varscan2
- OR4P4 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs143338269, COSV58923294; called by muse, mutect2, varscan2
- OR5D18 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV61737788, COSV61738604; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.980G>A p.R327H (on ENST00000259318 / NM_001136562.3; = p.R558H on NM_007203.5) | Missense Mutation (SNP) | VAF 67/188 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs755205853, COSV99395545; called by muse, varscan2
- PCDH15 | c.2323G>T p.V775L | Missense Mutation (SNP) | VAF 62/485 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.733); catalogued as COSV57268500; called by muse, mutect2, varscan2
- PCDHB8 | c.882G>T p.K294N | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.158); catalogued as COSV50753993; called by muse, mutect2
- PCDHGA5 | c.1233C>A p.D411E | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs754759386; called by muse, mutect2, varscan2
- PCLO | c.10452G>T p.M3484I | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100427551; called by muse, mutect2, varscan2
- PEPD | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.182); catalogued as COSV54894072; called by muse, mutect2
- PKHD1L1 | c.9901G>T p.V3301L | Missense Mutation (SNP) | VAF 22/292 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV65750434; called by muse, mutect2
- PLEKHH3 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs778023997; called by muse, mutect2, varscan2
- PLXNA4 | c.2098-1G>T p.X700_splice | Splice Site (SNP) | VAF 23/115 reads (20%) | catalogued as COSV58124293, COSV58145351; called by muse, mutect2, varscan2
- POTEF | c.2384G>A p.R795H | Missense Mutation (SNP) | VAF 228/700 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.478); catalogued as rs751923686; called by muse, mutect2, varscan2
- PPP1R8 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.196); catalogued as rs1272949541; called by muse, mutect2, varscan2
- PPP1R9B | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.913); catalogued as rs539885092; called by muse, mutect2, varscan2
- PRAMEF11 | c.25C>A p.P9T | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV101463179; called by muse, mutect2, varscan2
- PROS1 | c.853G>T p.V285F | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs1307450778; called by muse, mutect2, varscan2
- PRRX1 | c.581G>C p.G194A | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.981); catalogued as COSV53410751; called by muse, mutect2, varscan2
- QRFPR | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.826); catalogued as rs1453975555; called by muse, mutect2, varscan2
- RAPGEF4 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs373393896; called by muse, mutect2, varscan2
- RETNLB | c.316C>A p.R106S | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55466694; called by muse, mutect2, varscan2
- RGS7 | c.860C>A p.T287K | Missense Mutation (SNP) | VAF 27/370 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.844); catalogued as COSV58550062, COSV58557354; called by muse, mutect2
- RIMBP2 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs370254266, COSV55472045; called by muse, mutect2, varscan2
- RYR2 | c.2569C>A p.L857M | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV63685005; called by muse, mutect2, varscan2
- SDK1 | c.3649C>T p.R1217C | Missense Mutation (SNP) | VAF 123/471 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as rs758661396, COSV67357298, COSV67362495; called by muse, mutect2, varscan2
- SGCZ | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66006197; called by muse, mutect2, varscan2
- SIRPG | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 145/451 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs527643862, COSV53808185; called by muse, mutect2, varscan2
- SLC26A7 | c.1237A>G p.I413V | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT tolerated (0.97); PolyPhen probably damaging (0.987); catalogued as COSV99404347; called by muse, mutect2, varscan2
- SLIT3 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs751355143, COSV60590561; called by muse, mutect2, varscan2
- SLU7 | c.89G>T p.R30I | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51788576; called by muse, mutect2, varscan2
- SNTG1 | c.679C>A p.R227= | Splice Region (SNP) | VAF 22/169 reads (13%) | catalogued as COSV52471603; called by muse, mutect2, varscan2
- STUM | c.230T>A p.L77Q | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs966038399; called by muse, mutect2, varscan2
- SYNE1 | c.1351G>C p.D451H (on ENST00000367255 / NM_182961.4; = p.D458H on NM_033071.3) | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99567719; called by muse, mutect2, varscan2
- TCEAL2 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61197184; called by muse, varscan2
- TNXB | c.8197C>T p.R2733W (on ENST00000647633; = p.R2486W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs752650618, COSV64480435; called by muse, mutect2, varscan2
- TSSK1B | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs373083902; called by muse, mutect2, varscan2
- WSCD1 | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 75/255 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs1451151924; called by muse, mutect2, varscan2
- XIRP2 | c.4072C>A p.P1358T (on ENST00000628543; = p.P1533T on NM_152381.6) | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99738595; called by muse, mutect2, varscan2
- ZFC3H1 | c.2606C>T p.T869I | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs376939632; called by muse, varscan2
- ZFR | c.2791G>T p.D931Y | Missense Mutation (SNP) | VAF 74/257 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54058476; called by muse, varscan2
- ZNF135 | c.461C>G p.T154R (on ENST00000313434 / NM_001289401.2; = p.T166R on NM_003436.4) | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs746765542, COSV57881402, COSV57884583; called by muse, mutect2, varscan2
- ZNF33B | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 23/196 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV100847819; called by muse, mutect2, varscan2
- ZNF492 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.958); catalogued as COSV71762382; called by muse, mutect2, varscan2
- ZNF610 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 57/120 reads (48%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.548); catalogued as rs770329068; called by muse, mutect2, varscan2
- ZNF676 | c.189G>T p.W63C (on ENST00000650058; = p.W31C on NM_001001411.3) | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as rs760740767; called by muse, mutect2
- ZNF98 | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as COSV63337418; called by muse, mutect2, varscan2
- ABCA6 | c.424G>T p.G142* | Nonsense Mutation (SNP) | VAF 30/139 reads (22%) | called by muse, mutect2, varscan2
- ABL2 | c.3262G>T p.A1088S (on ENST00000502732 / NM_007314.4; = p.A1073S on NM_005158.5) | Missense Mutation (SNP) | VAF 62/287 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ADAM15 | c.544A>T p.S182C | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ADAM33 | c.245A>T p.E82V | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ADAM7 | c.25A>G p.M9V | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAMTS18 | c.2509A>T p.T837S | Missense Mutation (SNP) | VAF 131/386 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ADGRB3 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADGRG4 | c.3270G>T p.E1090D | Missense Mutation (SNP) | VAF 76/144 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- AHNAK2 | c.3114G>T p.Q1038H | Missense Mutation (SNP) | VAF 59/432 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AK2 | c.287G>T p.R96I (on ENST00000354858; = p.R138I on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/249 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- AKT2 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 58/532 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- AKT3 | c.716G>T p.R239I | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AL136295.1 | c.491A>T p.E164V | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALDH16A1 | c.1099-2A>G p.X367_splice | Splice Site (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- ALMS1 | c.1568G>T p.S523I | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ALS2CL | c.1751G>T p.C584F | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- AMPD1 | c.990C>A p.C330* | Nonsense Mutation (SNP) | VAF 122/332 reads (37%) | called by muse, mutect2, varscan2
- ANK2 | c.4105A>T p.R1369* | Nonsense Mutation (SNP) | VAF 53/239 reads (22%) | called by muse, mutect2, varscan2
- ANKRD31 | c.4529G>T p.G1510V | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ANKRD31 | c.4528G>A p.G1510R | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP23 | c.3655G>T p.G1219C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- ASIC3 | c.424C>A p.P142T | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.089); called by muse, mutect2
- ATM | c.7516-7A>G | Splice Region (SNP) | VAF 138/237 reads (58%) | called by muse, mutect2, varscan2
- ATP10B | c.1435C>A p.Q479K | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATR | c.2289C>G p.C763W | Missense Mutation (SNP) | VAF 62/103 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- BOD1L1 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 99/324 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BTBD11 | c.1309C>G p.H437D | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BTBD9 | c.153G>T p.R51S | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- BTD | c.655A>T p.R219W | Missense Mutation (SNP) | VAF 132/323 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CABLES2 | c.880G>C p.G294R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- CACNA1C | c.2636C>A p.A879E | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CACNA2D3 | c.1702G>T p.D568Y | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CAMK4 | c.486_487del p.H162Qfs*2 | Frame Shift Del (DEL) | VAF 32/113 reads (28%) | called by mutect2, pindel*
- CAMTA1 | c.3026G>T p.G1009V | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); called by muse, mutect2
- CAVIN1 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CCDC136 | c.1013A>C p.Q338P | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC74A | c.545-2_545-1insT p.X182_splice | Splice Site (INS) | VAF 51/115 reads (44%) | called by mutect2, pindel, varscan2
- CCDC91 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.202); called by muse, mutect2
- CDCA2 | c.2177G>T p.S726I | Missense Mutation (SNP) | VAF 43/204 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CDK1 | c.195-6_196delinsTTTTTTTT p.X65_splice | Splice Site (ONP) | VAF 10/113 reads (9%) | called by mutect2*, pindel
- CENPE | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- CEP126 | c.3013G>A p.G1005S | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- CHGA | c.59C>A p.P20H | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLEC5A | c.478A>T p.N160Y | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- CNTNAP4 | c.315G>C p.W105C | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL16A1 | c.3682-1G>T p.X1228_splice | Splice Site (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- CPS1 | c.1369G>T p.V457F | Missense Mutation (SNP) | VAF 13/326 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- CSNK1A1L | c.814C>A p.P272T | Missense Mutation (SNP) | VAF 159/364 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, varscan2
- CTNND2 | c.578C>G p.T193R | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CTSF | c.722-2A>C p.X241_splice | Splice Site (SNP) | VAF 101/160 reads (63%) | called by muse, mutect2, varscan2
- CYP2W1 | c.989T>A p.L330Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- DCANP1 | c.379G>T p.G127* | Nonsense Mutation (SNP) | VAF 25/136 reads (18%) | called by muse, mutect2, varscan2
- DGKE | c.1105A>G p.T369A | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DNAH14 | c.5428A>T p.K1810* (on ENST00000445597; = p.K2215* on NM_001367479.1) | Nonsense Mutation (SNP) | VAF 73/264 reads (28%) | called by muse, mutect2, varscan2
- DNAI1 | c.1118C>G p.P373R | Missense Mutation (SNP) | VAF 57/385 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- DPP9 | c.1328G>T p.R443L (on ENST00000598800; = p.R472L on NM_139159.5) | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- DYSF | c.3178A>T p.R1060W | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- F5 | c.6413C>A p.T2138K | Missense Mutation (SNP) | VAF 112/463 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM183A | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 38/520 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- FBN2 | c.4471+4G>C | Splice Region (SNP) | VAF 96/425 reads (23%) | called by muse, mutect2, varscan2
- FBXO7 | c.211G>T p.G71W | Missense Mutation (SNP) | VAF 66/322 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCRL4 | c.721A>T p.S241C | Missense Mutation (SNP) | VAF 144/594 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FOCAD | c.2325G>T p.E775D | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FOLR1 | c.197G>T p.C66F | Missense Mutation (SNP) | VAF 345/561 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXP2 | c.1418G>T p.G473V | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GBX2 | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLDC | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 57/458 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- GOLGA8Q | c.1487T>A p.L496* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | called by mutect2, varscan2
- GPRC6A | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 78/228 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, varscan2
- HCN2 | c.2548C>T p.P850S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- HFM1 | c.1274T>C p.L425P | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMX1 | c.254C>A p.A85E | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- HPSE2 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 95/173 reads (55%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- HS6ST1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 89/635 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSFX2 | c.136C>G p.P46A | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.009); called by mutect2, varscan2
- IGKV1-5 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 59/366 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- INSRR | c.34T>A p.C12S | Missense Mutation (SNP) | VAF 105/291 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, varscan2
- INSYN2B | c.206A>T p.Q69L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- ITGAL | c.647A>G p.D216G | Missense Mutation (SNP) | VAF 124/321 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ITGAM | c.1008G>T p.E336D | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIAA1549L | c.3732G>T p.E1244D (on ENST00000321505; = p.E1541D on NM_012194.3) | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.069); called by muse, mutect2
- KIRREL1 | c.1345G>T p.G449C | Missense Mutation (SNP) | VAF 82/342 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KMO | c.1327C>T p.H443Y | Missense Mutation (SNP) | VAF 118/412 reads (29%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP1-5 | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 13/337 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.386); called by muse, mutect2
- L3MBTL2 | c.521-12_521-3delinsG | Splice Region (DEL) | VAF 40/144 reads (28%) | called by pindel, varscan2*
- LBX1 | c.129C>A p.N43K | Missense Mutation (SNP) | VAF 148/416 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- LGALSL | c.329A>T p.Q110L | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- LOXHD1 | c.6057G>T p.E2019D (on ENST00000642948; = p.E1957D on NM_144612.7) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- LRFN5 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 194/363 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRP1B | c.7855G>T p.A2619S | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- LRRC7 | c.4186C>G p.P1396A (on ENST00000651989 / NM_001370785.2; = p.P1316A on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- LRRC71 | c.1428C>A p.H476Q | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, varscan2
- MAGEL2 | c.599C>A p.A200D | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MARVELD2 | c.244G>T p.V82F | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- MDGA1 | c.1504G>C p.E502Q | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- MEOX1 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- MEX3B | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 53/329 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- MOGAT2 | c.735T>A p.Y245* | Nonsense Mutation (SNP) | VAF 281/451 reads (62%) | called by muse, mutect2, varscan2
- MROH7 | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 137/308 reads (44%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRPL10 | c.712A>G p.R238G | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MS4A4E | c.371G>C p.G124A | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MUC19 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 79/293 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC5B | c.4041C>A p.H1347Q | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2
- MUC5B | c.4042C>A p.R1348S | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.148); called by muse, mutect2
- MYBPH | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 15/418 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2
- MYH3 | c.3914G>T p.S1305I | Missense Mutation (SNP) | VAF 102/450 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYLK3 | c.2095G>T p.G699* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- MYO18B | c.5760C>G p.D1920E | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MYOM1 | c.3715C>A p.H1239N | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- NBEA | c.6635T>A p.I2212K | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NBPF15 | c.1397C>A p.S466* | Nonsense Mutation (SNP) | VAF 138/879 reads (16%) | called by muse, mutect2, varscan2
- NEB | c.9898G>T p.D3300Y | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP8 | c.1149del p.M384Wfs*23 | Frame Shift Del (DEL) | VAF 77/184 reads (42%) | called by mutect2, pindel, varscan2
- NMRK2 | c.126C>A p.D42E | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NT5C1A | c.976T>A p.F326I | Missense Mutation (SNP) | VAF 498/651 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- OR10A5 | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, varscan2
- OR2AJ1 | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, varscan2
- OR2T11 | c.91G>T p.V31F | Missense Mutation (SNP) | VAF 88/344 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- OR2T12 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 118/574 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.955); called by muse, varscan2
- OR4B1 | c.919G>T p.G307W | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, varscan2
- OR52M1 | c.587G>T p.R196M | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- OR5R1 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OTOG | c.7140G>C p.Q2380H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- PACSIN3 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- PCDH1 | c.2227G>T p.D743Y | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH17 | c.2749G>T p.A917S | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- PCDHB4 | c.2176G>T p.V726L | Missense Mutation (SNP) | VAF 72/364 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCDHB6 | c.1024G>T p.A342S | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PCDHGA7 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by mutect2, varscan2
- PCDHGA7 | c.448del p.V150Ffs*5 | Frame Shift Del (DEL) | VAF 42/280 reads (15%) | called by mutect2, pindel, varscan2
- PCSK2 | c.442G>T p.V148L | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PDE6A | c.1490A>T p.D497V | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PEMT | c.301G>T p.V101F | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PEX5L | c.299C>A p.S100Y | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PGM5 | c.1000C>A p.R334S | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PHLPP1 | c.2533G>T p.D845Y | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- PLCB1 | c.375A>T p.E125D | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLG | c.1288G>C p.D430H | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLR1B | c.1453A>T p.T485S | Missense Mutation (SNP) | VAF 70/405 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, varscan2
- POLR2H | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- PPARGC1B | c.2096G>T p.R699L | Missense Mutation (SNP) | VAF 86/362 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.095); called by muse, varscan2
- PPFIA4 | c.1643C>A p.P548H (on ENST00000447715; = p.A537= on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/344 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- PPIG | c.1872G>T p.R624S | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PPP4R3C | c.575A>T p.H192L | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- PRKD1 | c.2236A>T p.T746S | Missense Mutation (SNP) | VAF 40/313 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PRPH | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- PSMD12 | c.202G>T p.V68F | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PTPRN | c.1088T>A p.L363Q | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- RAB21 | c.67G>T p.V23L | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- RADIL | c.3074G>T p.R1025L | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- RAG1 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 122/313 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RFPL1 | c.539A>T p.H180L | Missense Mutation (SNP) | VAF 48/248 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RHOBTB3 | c.1653G>T p.W551C | Missense Mutation (SNP) | VAF 67/297 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- RIN1 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 390/645 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RTN3 | c.1952dup p.E652Rfs*13 (on ENST00000377819 / NM_001265589.2; = p.E633Rfs*13 on NM_201428.3) | Frame Shift Ins (INS) | VAF 20/95 reads (21%) | called by mutect2, pindel, varscan2
- RYR3 | c.461C>G p.P154R | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SALL4 | c.1024G>T p.V342L | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SCN4A | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SCN8A | c.1762C>G p.H588D | Missense Mutation (SNP) | VAF 71/302 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- SERPINA12 | c.611T>C p.L204P | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD1B | c.5426C>T p.T1809I | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- SGCG | c.415C>A p.Q139K | Missense Mutation (SNP) | VAF 158/384 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SGCZ | c.659C>A p.P220H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIRT5 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 54/155 reads (35%) | called by muse, mutect2, varscan2
- SLC22A7 | c.460G>T p.G154C (on ENST00000372585 / NM_153320.2; = p.G152C on NM_006672.3) | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SLC22A7 | c.461G>T p.G154V (on ENST00000372585 / NM_153320.2; = p.G152V on NM_006672.3) | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLFN14 | c.551G>T p.R184M | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- SMYD1 | c.1460A>G p.H487R | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOX17 | c.465C>G p.F155L | Missense Mutation (SNP) | VAF 23/122 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SPATA31A1 | c.769C>G p.H257D | Missense Mutation (SNP) | VAF 55/569 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- SPATA31A6 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 91/499 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- SPATA31A7 | c.1334del p.F445Sfs*73 | Frame Shift Del (DEL) | VAF 18/66 reads (27%) | called by mutect2, varscan2
- SPHKAP | c.3242C>G p.S1081C | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- STYXL2 | c.1804A>T p.S602C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- SUMO1 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 83/245 reads (34%) | called by muse, mutect2, varscan2
- SVEP1 | c.4387A>G p.M1463V | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- SVOPL | c.819G>T p.L273F (on ENST00000419765; = p.L121F on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SYNCRIP | c.1538G>C p.G513A | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SYT16 | c.890G>T p.R297M | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TADA2A | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAF1L | c.5276T>A p.V1759D | Missense Mutation (SNP) | VAF 146/430 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEP1 | c.51G>T p.L17F | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- TMC2 | c.1754G>T p.R585M | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- TMEM131 | c.2212G>T p.A738S | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TNFRSF21 | c.585G>C p.Q195H | Missense Mutation (SNP) | VAF 81/493 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TNXB | c.7007C>A p.A2336D (on ENST00000647633; = p.A2089D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- TOPBP1 | c.2662A>T p.S888C | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- TRAJ38 | c.19C>A p.R7S | Missense Mutation (SNP) | VAF 52/247 reads (21%) | called by muse, mutect2, varscan2
- TRIM72 | c.1241G>T p.G414V | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPA1 | c.2965A>T p.K989* | Nonsense Mutation (SNP) | VAF 59/304 reads (19%) | called by muse, mutect2, varscan2
- TRPV2 | c.1654+1G>T p.X552_splice | Splice Site (SNP) | VAF 33/160 reads (21%) | called by muse, mutect2, varscan2
- TSHZ3 | c.1647C>G p.S549R | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TTN | c.81437T>G p.L27146W (on ENST00000591111; = p.L19722W on NM_003319.4) | Missense Mutation (SNP) | VAF 21/52 reads (40%) | PolyPhen benign (0.28); called by muse, mutect2, varscan2
- TUBAL3 | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TUFT1 | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- TXLNB | c.654C>A p.C218* | Nonsense Mutation (SNP) | VAF 70/190 reads (37%) | called by muse, varscan2
- UBR4 | c.2202G>T p.Q734H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.948); called by muse, varscan2
- UHMK1 | c.562-1G>T p.X188_splice | Splice Site (SNP) | VAF 22/96 reads (23%) | called by muse, varscan2
- UNC13B | c.3830T>A p.L1277H | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UNC5D | c.2838C>A p.N946K | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP1 | c.1073T>G p.L358R | Missense Mutation (SNP) | VAF 72/111 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- USP34 | c.4820A>G p.N1607S | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- USP34 | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- VAX1 | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- VPS13D | c.3302A>G p.Q1101R | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.155); called by muse, mutect2
- VWA2 | c.1022G>C p.R341T | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZAP70 | c.1447T>A p.S483T | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZFP82 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZMYND8 | c.2555A>T p.Q852L | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF469 | c.6878G>T p.R2293M (on ENST00000437464; = p.R2321M on NM_001367624.2) | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ZNF729 | c.2536C>A p.H846N | Missense Mutation (SNP) | VAF 125/417 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZRANB3 | c.82T>G p.F28V | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.086); called by muse, varscan2
- ACE | c.2313G>A p.T771= | Silent (SNP) | VAF 94/324 reads (29%) | catalogued as rs747443207, COSV52012843; called by muse, mutect2
- ADAMTSL2 | c.267C>A p.T89= | Silent (SNP) | VAF 135/323 reads (42%) | called by muse, mutect2, varscan2
- ADGRG4 | c.3483G>T p.V1161= | Silent (SNP) | VAF 83/155 reads (54%) | called by muse, mutect2, varscan2
- AKAP9 | c.615C>T p.G205= | Silent (SNP) | VAF 35/180 reads (19%) | called by muse, mutect2, varscan2
- ART1 | c.312C>A p.S104= | Silent (SNP) | VAF 42/99 reads (42%) | called by muse, mutect2, varscan2
- ASIC3 | c.426C>A p.P142= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV99874409; called by muse, mutect2
- BCAT1 | c.27C>T p.S9= | Silent (SNP) | VAF 126/352 reads (36%) | catalogued as rs79721387, COSV99678921; called by muse, varscan2
- BMP15 | c.1158T>A p.A386= | Silent (SNP) | VAF 59/213 reads (28%) | called by muse, mutect2, varscan2
- BORCS6 | c.1011G>A p.G337= | Silent (SNP) | VAF 62/400 reads (16%) | catalogued as rs760884081; called by muse, mutect2, varscan2
- CACNA1H | c.3543C>T p.D1181= | Silent (SNP) | VAF 11/249 reads (4%) | catalogued as rs958144782, COSV61987153; called by muse, mutect2
- CCDC166 | c.357C>T p.R119= | Silent (SNP) | VAF 34/213 reads (16%) | called by muse, mutect2, varscan2
- CD37 | c.339C>T p.A113= | Silent (SNP) | VAF 84/174 reads (48%) | catalogued as COSV100115193; called by muse, mutect2, varscan2
- CDC20B | c.1413G>T p.V471= | Silent (SNP) | VAF 32/213 reads (15%) | catalogued as COSV57054221; called by muse, mutect2, varscan2
- CFAP46 | c.1611C>A p.S537= | Silent (SNP) | VAF 38/86 reads (44%) | called by muse, varscan2
- CHM | c.1041A>T p.T347= | Silent (SNP) | VAF 112/230 reads (49%) | called by muse, mutect2, varscan2
- CHRD | c.360C>T p.H120= | Silent (SNP) | VAF 66/168 reads (39%) | catalogued as rs1451317697; called by muse, mutect2, varscan2
- CHRM1 | c.1093C>A p.R365= | Silent (SNP) | VAF 75/181 reads (41%) | called by muse, mutect2, varscan2
- CLTCL1 | c.3117G>A p.R1039= | Silent (SNP) | VAF 46/167 reads (28%) | catalogued as COSV54232600; called by muse, mutect2, varscan2
- COL3A1 | c.180T>A p.V60= | Silent (SNP) | VAF 96/376 reads (26%) | called by muse, mutect2, varscan2
- COL3A1 | c.3423T>G p.P1141= | Silent (SNP) | VAF 120/447 reads (27%) | called by muse, mutect2, varscan2
- COL4A2 | c.1350T>C p.F450= | Silent (SNP) | VAF 196/448 reads (44%) | called by muse, varscan2
- CPXM1 | c.2127C>T p.R709= | Silent (SNP) | VAF 21/248 reads (8%) | catalogued as rs746717725; called by muse, mutect2
- CUX2 | c.4038C>T p.P1346= | Silent (SNP) | VAF 84/245 reads (34%) | catalogued as rs747156390, COSV99919706; called by muse, mutect2, varscan2
- DACT1 | c.1593C>A p.P531= | Silent (SNP) | VAF 104/273 reads (38%) | called by muse, mutect2, varscan2
- DYDC2 | c.294C>T p.S98= | Silent (SNP) | VAF 134/220 reads (61%) | called by muse, varscan2
- EIF4G3 | c.2721A>G p.E907= | Silent (SNP) | VAF 50/225 reads (22%) | called by muse, mutect2, varscan2
- EMILIN1 | c.1326C>T p.A442= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV53153262; called by muse, mutect2, varscan2
- ENTPD1 | c.1023C>A p.S341= | Silent (SNP) | VAF 60/345 reads (17%) | called by muse, mutect2, varscan2
- ERCC3 | c.1761G>A p.G587= | Silent (SNP) | VAF 62/226 reads (27%) | catalogued as rs1280410861; called by muse, varscan2
- EVC | c.1449G>T p.P483= | Silent (SNP) | VAF 135/426 reads (32%) | catalogued as COSV53837264; called by muse, mutect2, varscan2
- EXO5 | c.906G>T p.V302= | Silent (SNP) | VAF 441/633 reads (70%) | called by muse, mutect2, varscan2
- FBN2 | c.8121T>C p.N2707= | Silent (SNP) | VAF 78/374 reads (21%) | called by muse, mutect2, varscan2
- FSHR | c.168C>A p.T56= | Silent (SNP) | VAF 85/369 reads (23%) | catalogued as COSV58621073; called by muse, mutect2, varscan2
- IGHD | c.1218C>A p.T406= | Silent (SNP) | VAF 121/393 reads (31%) | called by muse, mutect2, varscan2
- IGHV3-35 | c.102G>C p.G34= | Silent (SNP) | VAF 51/318 reads (16%) | called by muse, mutect2, varscan2
- IGKV6-21 | c.117C>A p.T39= | Silent (SNP) | VAF 31/299 reads (10%) | called by muse, mutect2
- IQSEC3 | c.180G>T p.L60= | Silent (SNP) | VAF 57/295 reads (19%) | called by muse, mutect2, varscan2
- ISLR | c.1200C>A p.V400= | Silent (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- KLHL20 | c.999C>T p.S333= | Silent (SNP) | VAF 57/147 reads (39%) | catalogued as rs1359853086; called by muse, mutect2, varscan2
- LCE1A | c.42C>T p.P14= | Silent (SNP) | VAF 50/133 reads (38%) | called by muse, mutect2, varscan2
- LILRB5 | c.178C>T p.L60= | Silent (SNP) | VAF 22/344 reads (6%) | called by muse, mutect2
- LVRN | c.351C>T p.P117= | Silent (SNP) | VAF 34/176 reads (19%) | called by muse, mutect2, varscan2
- LY6H | c.417G>T p.G139= | Silent (SNP) | VAF 102/188 reads (54%) | catalogued as COSV100713949; called by muse, mutect2
- LYPD8 | c.543G>T p.L181= | Silent (SNP) | VAF 170/438 reads (39%) | called by muse, mutect2, varscan2
- MAP10 | c.2583C>T p.T861= | Silent (SNP) | VAF 71/183 reads (39%) | called by muse, mutect2, varscan2
- MRGPRX4 | c.180T>A p.A60= | Silent (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- MS4A8 | c.540T>A p.P180= | Silent (SNP) | VAF 81/216 reads (38%) | called by muse, mutect2, varscan2
- MYH8 | c.1440C>T p.C480= | Silent (SNP) | VAF 96/437 reads (22%) | catalogued as rs1335738728, COSV101238472; called by muse, mutect2, varscan2
- NEB | c.18471T>C p.D6157= | Silent (SNP) | VAF 18/96 reads (19%) | called by muse, mutect2, varscan2
- NOS1 | c.1245G>T p.R415= | Silent (SNP) | VAF 75/230 reads (33%) | catalogued as COSV57617910; called by muse, mutect2, varscan2
- NTRK3 | c.339A>T p.S113= | Silent (SNP) | VAF 61/390 reads (16%) | called by muse, mutect2, varscan2
- OR2M4 | c.822G>T p.V274= | Silent (SNP) | VAF 17/269 reads (6%) | catalogued as rs1461317754; called by muse, mutect2
- OR4C15 | c.654G>A p.Q218= (on ENST00000314644; = p.Q164= on NM_001001920.2) | Silent (SNP) | VAF 71/188 reads (38%) | called by muse, mutect2, varscan2
- OR51L1 | c.99C>T p.F33= | Silent (SNP) | VAF 56/149 reads (38%) | catalogued as COSV58623923; called by muse, mutect2, varscan2
- OR7A17 | c.429C>T p.L143= | Silent (SNP) | VAF 58/132 reads (44%) | catalogued as rs769020214; called by muse, mutect2, varscan2
- PDILT | c.448C>A p.R150= | Silent (SNP) | VAF 62/159 reads (39%) | catalogued as rs139247719, COSV56700444; called by muse, mutect2, varscan2
- PLEC | c.9513G>T p.A3171= (on ENST00000322810 / NM_201380.4; = p.A3061= on NM_000445.5) | Silent (SNP) | VAF 167/791 reads (21%) | catalogued as COSV59674993; called by muse, mutect2, varscan2
- PLEKHH3 | c.456G>T p.S152= | Silent (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- PLEKHM1 | c.777A>T p.S259= | Silent (SNP) | VAF 106/562 reads (19%) | called by muse, mutect2, varscan2
- PLSCR5 | c.669A>C p.S223= | Silent (SNP) | VAF 57/141 reads (40%) | called by muse, mutect2, varscan2
- PNMA8A | c.996C>T p.A332= | Silent (SNP) | VAF 42/68 reads (62%) | called by muse, mutect2, varscan2
- PPFIA2 | c.2287C>A p.R763= | Silent (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.363C>A p.L121= | Silent (SNP) | VAF 39/432 reads (9%) | catalogued as rs757084218; called by muse, mutect2
- PTPRH | c.2898C>T p.L966= | Silent (SNP) | VAF 83/160 reads (52%) | catalogued as COSV54745636; called by muse, mutect2, varscan2
- PTPRQ | c.6804G>C p.L2268= (on ENST00000616559; = p.L2235= on NM_001145026.2) | Silent (SNP) | VAF 60/229 reads (26%) | called by muse, mutect2, varscan2
- PTPRT | c.3957C>A p.I1319= | Silent (SNP) | VAF 58/204 reads (28%) | called by muse, mutect2, varscan2
- RASGRP4 | c.456C>T p.T152= | Silent (SNP) | VAF 51/118 reads (43%) | catalogued as rs1048545329, COSV53094725; called by muse, mutect2, varscan2
- RYR2 | c.12222G>A p.E4074= | Silent (SNP) | VAF 34/411 reads (8%) | catalogued as COSV63678320, COSV63720590; called by muse, mutect2
- SDK2 | c.3486C>A p.I1162= | Silent (SNP) | VAF 69/335 reads (21%) | catalogued as COSV66196750; called by muse, mutect2, varscan2
- SGIP1 | c.1992C>A p.P664= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV52773045; called by muse, mutect2, varscan2
- SI | c.5436C>T p.T1812= | Silent (SNP) | VAF 9/229 reads (4%) | catalogued as rs1274683613; called by muse, mutect2
- SLC13A5 | c.1521C>T p.A507= | Silent (SNP) | VAF 38/153 reads (25%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.1332C>A p.A444= | Silent (SNP) | VAF 64/95 reads (67%) | catalogued as COSV56935363; called by muse, mutect2, varscan2
- SMARCC2 | c.597G>A p.K199= | Silent (SNP) | VAF 56/222 reads (25%) | catalogued as rs1451286231; called by muse, varscan2
- SOX14 | c.345C>T p.S115= | Silent (SNP) | VAF 86/147 reads (59%) | catalogued as rs765282750; called by muse, mutect2, varscan2
- SPATC1 | c.27G>A p.G9= | Silent (SNP) | VAF 38/333 reads (11%) | called by muse, mutect2, varscan2
- SYNGR4 | c.48G>A p.V16= | Silent (SNP) | VAF 113/258 reads (44%) | called by muse, mutect2, varscan2
- TENM4 | c.48C>T p.R16= | Silent (SNP) | VAF 12/321 reads (4%) | catalogued as rs1218746162; called by muse, mutect2
- TEX15 | c.117C>T p.T39= (on ENST00000638951; = p.T35= on NM_001350162.2) | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as rs1294908974; called by muse, mutect2, varscan2
- TTYH2 | c.1359C>T p.F453= | Silent (SNP) | VAF 32/171 reads (19%) | catalogued as rs773175819; called by muse, mutect2, varscan2
- UPK1A | c.165A>T p.S55= | Silent (SNP) | VAF 160/401 reads (40%) | called by muse, mutect2, varscan2
- VCAN | c.7116T>C p.S2372= | Silent (SNP) | VAF 108/321 reads (34%) | catalogued as rs779690845; called by muse, mutect2, varscan2
- YEATS2 | c.357A>T p.P119= | Silent (SNP) | VAF 115/268 reads (43%) | called by muse, mutect2, varscan2
- AC114490.3 | c.*702G>T | 3'UTR (SNP) | VAF 44/208 reads (21%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.2575+52A>G | Intron (SNP) | VAF 68/358 reads (19%) | called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668441 G>A | 5'Flank (SNP) | VAF 40/160 reads (25%) | called by muse, varscan2
- AL353804.7 | chrX:73846694 T>A | 5'Flank (SNP) | VAF 129/219 reads (59%) | called by muse, mutect2, varscan2
- ARMC8 | c.*14G>A | 3'UTR (SNP) | VAF 21/124 reads (17%) | called by muse, mutect2, varscan2
- ATRNL1 | c.3795+48099G>T | Intron (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- BRCA1 | c.*875G>T | 3'UTR (SNP) | VAF 18/49 reads (37%) | catalogued as COSV58789240; called by mutect2, varscan2
- CALY | c.*1060C>A | 3'UTR (SNP) | VAF 33/54 reads (61%) | called by muse, varscan2
- CATIP | c.-21G>T | 5'UTR (SNP) | VAF 74/244 reads (30%) | called by muse, mutect2, varscan2
- CEACAM4 | c.669+30C>T | Intron (SNP) | VAF 6/58 reads (10%) | catalogued as rs1443532431, COSV99701266; called by muse, mutect2
- CEACAM4 | c.669+29C>A | Intron (SNP) | VAF 6/58 reads (10%) | called by muse, mutect2
- CFAP46 | c.4511+59C>A | Intron (SNP) | VAF 206/351 reads (59%) | called by muse, mutect2, varscan2
- CHMP1A | c.381+146G>T | Intron (SNP) | VAF 18/98 reads (18%) | catalogued as COSV53684476; called by muse, mutect2
- CNTN6 | c.-447T>A | 5'UTR (SNP) | VAF 33/85 reads (39%) | called by muse, mutect2, varscan2
- COL9A3 | c.1401+41C>T | Intron (SNP) | VAF 48/348 reads (14%) | catalogued as rs757780997; called by muse, mutect2, varscan2
- CPA4 | chr7:130293141 C>T | 5'Flank (SNP) | VAF 57/263 reads (22%) | called by muse, mutect2, varscan2
- CPLANE1 | chr5:37165533 C>A | 3'Flank (SNP) | VAF 29/192 reads (15%) | called by muse, mutect2, varscan2
- CREM | c.121-8096G>T | Intron (SNP) | VAF 20/149 reads (13%) | called by muse, mutect2, varscan2
- DNAH14 | c.7486-5697G>T | Intron (SNP) | VAF 12/336 reads (4%) | called by muse, mutect2
- DPT | c.*9C>A | 3'UTR (SNP) | VAF 51/121 reads (42%) | called by muse, mutect2, varscan2
- EFHC1 | c.*1222A>T | 3'UTR (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- FAM215A | n.139G>T | RNA (SNP) | VAF 16/113 reads (14%) | called by muse, mutect2, varscan2
- GH1 | c.-49C>A | 5'UTR (SNP) | VAF 81/257 reads (32%) | called by muse, mutect2, varscan2
- GRM7 | c.2698+10929C>A | Intron (SNP) | VAF 21/95 reads (22%) | called by muse, mutect2, varscan2
- GUSBP10 | n.340G>T | RNA (SNP) | VAF 31/181 reads (17%) | called by muse, mutect2, varscan2
- HADHA | c.-17G>T | 5'UTR (SNP) | VAF 103/449 reads (23%) | called by muse, mutect2, varscan2
- HAND2 | c.*61G>T | 3'UTR (SNP) | VAF 66/168 reads (39%) | called by muse, mutect2, varscan2
- HLA-V | chr6:29792117 C>A | 5'Flank (SNP) | VAF 67/432 reads (16%) | called by muse, mutect2, varscan2
- HLA-V | chr6:29792118 A>G | 5'Flank (SNP) | VAF 67/428 reads (16%) | called by muse, mutect2, varscan2
- LINC01551 | n.1254+18769C>A | Intron (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- LINC02740 | n.341A>G | RNA (SNP) | VAF 65/195 reads (33%) | called by muse, mutect2, varscan2
- MAPK11 | c.447+19del | Intron (DEL) | VAF 59/268 reads (22%) | called by mutect2, pindel, varscan2
- MOG | c.*46G>A | 3'UTR (SNP) | VAF 41/192 reads (21%) | called by muse, mutect2, varscan2
- MYO16 | c.2806+1365C>T | Intron (SNP) | VAF 14/46 reads (30%) | catalogued as rs760206043; called by muse, mutect2, varscan2
- NCOA2 | c.*34G>T | 3'UTR (SNP) | VAF 21/149 reads (14%) | called by muse, mutect2, varscan2
- OR56B3P | n.468C>A | RNA (SNP) | VAF 95/252 reads (38%) | called by muse, mutect2, varscan2
- PAX8 | c.777+23G>A | Intron (SNP) | VAF 29/195 reads (15%) | catalogued as rs777851763; called by muse, mutect2, varscan2
- PKHD1 | c.10156+22371C>T | Intron (SNP) | VAF 91/296 reads (31%) | called by muse, mutect2, varscan2
- PLXDC1 | c.593-105C>A | Intron (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2
- PSG2 | c.*37G>C | 3'UTR (SNP) | VAF 62/164 reads (38%) | called by muse, mutect2, varscan2
- PSG3 | c.*6G>A | 3'UTR (SNP) | VAF 60/136 reads (44%) | catalogued as rs761028412; called by muse, varscan2
- PTPRC | c.658+39T>A | Intron (SNP) | VAF 114/350 reads (33%) | called by muse, mutect2, varscan2
- RBM7 | chr11:114414001 G>T | 3'Flank (SNP) | VAF 126/279 reads (45%) | called by muse, mutect2, varscan2
- RHAG | c.*74C>A | 3'UTR (SNP) | VAF 62/443 reads (14%) | called by muse, varscan2
- RNASE13 | c.*852G>A | 3'UTR (SNP) | VAF 21/190 reads (11%) | catalogued as rs1467605180; called by muse, mutect2
- RNF217-AS1 | n.4439A>C | RNA (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- RNU6-389P | chr7:55685222 G>T | 5'Flank (SNP) | VAF 33/183 reads (18%) | called by muse, mutect2, varscan2
- SLC25A13 | c.-128C>A | 5'UTR (SNP) | VAF 40/192 reads (21%) | called by muse, varscan2
- SPTA1 | c.6530+31C>G | Intron (SNP) | VAF 59/520 reads (11%) | called by muse, mutect2, varscan2
- TAAR3P | n.917G>A | RNA (SNP) | VAF 42/211 reads (20%) | catalogued as rs556227187; called by muse, mutect2, varscan2
- TMEM135 | c.*5097G>A | 3'UTR (SNP) | VAF 45/423 reads (11%) | catalogued as rs911927582; called by muse, mutect2, varscan2
- TP63 | c.325-18541G>T | Intron (SNP) | VAF 32/75 reads (43%) | called by mutect2, varscan2
- UBE2L3 | c.27+23G>T | Intron (SNP) | VAF 33/129 reads (26%) | catalogued as rs765404348; called by muse, mutect2, varscan2
- WT1 | chr11:32438368 C>A | 5'Flank (SNP) | VAF 66/172 reads (38%) | called by muse, mutect2, varscan2
- ZNF767P | n.333G>T | RNA (SNP) | VAF 57/314 reads (18%) | called by muse, mutect2, varscan2
- ZNF767P | n.332G>T | RNA (SNP) | VAF 55/318 reads (17%) | called by muse, mutect2, varscan2
